Gene-level copy-number profile of tumor specimen TCGA-DX-AATS-01A from TCGA case TCGA-DX-AATS, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 72.9 years (26,624 days).
Specimen TCGA-DX-AATS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.0209f46e-5169-41c8-8134-b140bca83612.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AATS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b689c4bb-a02d-4af1-af82-4ca72306a75a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 841; copy number 2: 7,660; copy number 3: 20,751; copy number 4: 14,320; copy number 5: 7,634; copy number 6: 5,008; copy number 7: 1,625; copy number 8: 1,089; copy number 9: 178; copy number 10: 418; copy number 11: 165; copy number 12: 75; copy number 13: 1; copy number 14: 6; copy number 16: 2; copy number 17: 5; copy number 20: 8; copy number 21: 5; copy number 22: 6; copy number 23: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AATS-01A-12D-A416-01): tumor purity 0.79, ploidy 4.05, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,134,358–48,599,436, 9 genes (within-gene range 0–2): POLR2KP2, ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,351 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,419,053–148,288,951, 32 genes, copy number 9: OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,344,638, 6 genes, copy number 9 (within-gene range 5–9): LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr2:211,375,717–224,039,318, 243 genes, copy number 8 (broad region; genes not listed).
- chr3:11,745–3,057,959, 25 genes, copy number 7–16 (within-gene range 5–16): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1.
- chr3:197,042,560–198,222,513, 36 genes, copy number 7 (within-gene range 4–7): DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:17,841,199–36,641,939, 143 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr4:44,944,015–45,051,652, 3 genes, copy number 10: PRDX4P1, AC108467.2, AC108467.1.
- chr5:58,198–24,449,615, 391 genes, copy number 9–14 (broad region; genes not listed).
- chr5:28,213,359–45,696,498, 280 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr6:46,096,004–47,042,350, 18 genes, copy number 7: AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:48,701,491–48,952,781, 3 genes, copy number 8: FO393412.1, AL391538.1, AL022099.1.
- chr6:70,394,881–70,561,174, 3 genes, copy number 22 (within-gene range 4–22): AL365226.1, FAM135A-AS1, FAM135A.
- chr6:99,993,934–100,178,192, 5 genes, copy number 17: MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1.
- chr6:143,864,436–144,064,599, 5 genes, copy number 20 (within-gene range 4–20): ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1.
- chr6:146,027,646–146,437,601, 4 genes, copy number 21 (within-gene range 4–21): GRM1, FUNDC2P3, RNA5SP222, AL035698.1.
- chr7:77,416,673–112,896,625, 597 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr7:114,560,961–116,258,783, 17 genes, copy number 10 (within-gene range 6–10): AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES.
- chr7:116,672,196–118,204,035, 41 genes, copy number 8–9: MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8.
- chr7:147,080,934–153,449,875, 163 genes, copy number 7–11 (broad region; genes not listed).
- chr7:155,181,881–155,644,406, 18 genes, copy number 7 (within-gene range 4–7): RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3.
- chr7:157,987,169–159,233,377, 16 genes, copy number 8: AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr9:85,492,579–85,936,599, 8 genes, copy number 7: STK33P1, AGTPBP1, AL353743.4, AL157882.1, AL353743.2, AL353743.1, PHBP7, AL353743.3.
- chr9:88,735,041–91,361,918, 42 genes, copy number 7 (within-gene range 5–7): AL390791.1, MIR4289, PCNPP2, AL772202.1, S1PR3, SHC3, AL353150.1, CKS2, MIR3153, SECISBP2, SEMA4D, PA2G4P6, AL590233.1, AL161910.1, GADD45G, UNQ6494, BX470209.2, BX470209.1, AL161629.1, MIR4290HG, MIR4290, IL6RP1, AL161629.2, AL353649.1, OR7E31P, OR7E116P, LINC01508, LINC01501, DIRAS2, OR7E109P, OR7E108P, SYK, AL162585.1, AL355607.1, AL355607.2, AL158071.3, AL158071.2, LINC00484, LINC00484, AL158071.1, AL158071.4, AUH.
- chr9:94,318,196–97,122,489, 76 genes, copy number 7 (broad region; genes not listed).
- chr9:98,199,011–101,482,199, 59 genes, copy number 7–9: TBC1D2, MIR6854, AL360081.1, GABBR2, SEPTIN7P7, ANKS6, AL807776.1, GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2, TGFBR1, RNA5SP290, AL162427.1, RN7SL794P, ALG2, SEC61B, RN7SKP225, KRT8P11, NAMA, AL137067.2, AL137067.3, AL137067.1, AL359710.1, STX17-AS1, AL162394.1, NR4A3, STX17, AL358937.1, ERP44, UPF3AP3, INVS, RN7SL75P, RPS2P35, AL137072.1, NANOGP5, TEX10, MSANTD3, MSANTD3-TMEFF1, TMEFF1, CAVIN4, RN7SKP87, ACTG1P19, AL162395.1, GAPDHP26, PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1.
- chr9:104,970,593–107,171,148, 29 genes, copy number 7–8: CT70, AL591506.1, RN7SKP191, SLC44A1, FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5, LINC01505, AL732323.1, AL451140.1, MIR8081, AL512649.2, RN7SKP77, AL512649.1, RNA5SP292, ZNF462, AL807761.4, AL512593.1, AL807761.1, AL807761.2, AL807761.3, AL445487.1.
- chr9:107,963,703–108,254,820, 4 genes, copy number 8: RPS15AP27, AC068050.1, CHCHD4P2, AL353742.1.
- chr9:119,935,053–123,930,152, 82 genes, copy number 7 (broad region; genes not listed).
- chr12:115,569,394–125,143,333, 289 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr18:47,390–500,722, 12 genes, copy number 7: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2.
- chr18:706,523–2,805,017, 37 genes, copy number 7–8 (within-gene range 4–8): AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1.
- chr18:3,347,696–3,478,978, 7 genes, copy number 7: LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:4,264,602–5,630,700, 20 genes, copy number 7: DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1.
- chr18:9,102,630–9,538,114, 15 genes, copy number 7: NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P.
- chr18:11,326,270–11,670,165, 14 genes, copy number 7: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1.
- chr18:30,713,275–31,556,948, 18 genes, copy number 7: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1.
- chr18:49,431,744–53,629,990, 69 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr19:14,031,762–17,075,625, 165 genes, copy number 7 (broad region; genes not listed).
- chr19:22,832,291–35,684,201, 286 genes, copy number 7–8 (broad region; genes not listed).
- chr20:9,505,180–13,300,651, 55 genes, copy number 7–10: LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1.

Autosomal genes at a single copy (total copy number 1): 841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
